Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A2BM, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A2BM-01A (Primary Tumor).

[page 1 of 3]
[Back to List](#)

TEST: Surgical Pathology

Date & Time:

REPORT STATUS: Final

FACILITY:

Patient:

Surgical Pathology

SURGICAL PATHOLOGY REPORT

See Addendum

HRAS Discrepancy		X
Distal Synchronous Primary		X
Percent in (re)classified	See below	See below

RMT for 5/27/11 5/12/11

Patient Name: 1

Accession #

Med. Rec. #:

Billing Type: Inpatient

Location:

DOB:

Age:

Service: Surgery

Gender: F

Billing #:

Taken Received

Physician(s):

Reported:

Specimen(s) Received

- A: Left sentinel nodes
- B: Left sentinel node #2
- C: Left breast tissue
- D: Left axillary contents

Pathologic Diagnosis

"A" - Left sentinel node: Metastatic carcinoma in one (of one) lymph node. Two foci of metastatic tumor are present, the larger measuring 0.3 cm. The metastatic tumor is confined to the lymph node.

"B" - Left sentinel lymph node #2: One lymph node negative for malignancy.

C. Left breast tissue:

Histologic Type: Invasive ductal carcinoma (NO#)

Modified B-R Grade: 3

Tubular score: 3

Nuclear score: 3

Mitosis score: 3

Tumor Size: Greatest dimension: 2.5 cm

Additional dimensions: 1.5 X

Regional Lymph Nodes: Number of lymph nodes examined: 13

Number of lymph nodes involved: 1

Metastasis detected by light microscopy

Margins of Invasive Carcinoma: Negative

Invasive carcinoma is located: 3 cm

away from the deep margin

Lymphovascular Invasion: Absent

Ductal Carcinoma In Situ: Absent

Paget's Disease: Absent

Distant Metastasis: Cannot be assessed

1CD-0-3

carcinoma, infiltrating duct, NOS 8500/3

Site: breast, NOS C50.9 for 5/27/11

[page 2 of 3]
Microcalcifications: Absent
Additional Pathologic Findings: Fibroadenomas
Specimen Type: Mastectomy
Specimen Size: Greatest dimension: 28 cm
Tumor Laterality: Left
Tumor Site: Upper inner quadrant
Lower inner quadrant
Lymph Node Sampling: Sentinel lymph nodes and axillary
dissection
Comment: In Part "C", one contiguous lymph node is negative
for malignancy. H&E and cytokeratin stains examined.

PT2 pN1a pMX

"D" - Left axillary contents: Ten lymph nodes negative for
malignancy.

Left axillary contents:
ESTROGEN AND PROGESTERONE RECEPTOR SYNOPSIS
Estrogen and progesterone receptor immunohistochemistry stains
are performed utilizing the 6f11 (ER) and 1A6 clones (PR) along
with the iVIEW detection kit. The stains are performed on
formalin-fixed paraffin-embedded sections. Both special stains
have adequate controls.

ESTROGEN RECEPTORS:

60 % Infiltrating malignant cells showing positive staining:

PROGESTERONE RECEPTORS:

10 % Infiltrating malignant cells showing positive staining:

ESTROGEN RECEPTOR RESULTS: Positive.

PROGESTERONE RECEPTOR RESULTS: Positive.

Note:

Consensus

Statement on Adjuvant Therapy for Breast Cancer:
Any positive nuclear ER immunostaining is considered a positive
result. These immunohistochemistry reaction patterns were
developed and their performance characteristics determined by
. They have not been cleared or
approved by the U.S. Food and Drug Administration. The FDA has
determined that such clearance or approval is not necessary.
These tests are used for clinical purposes. They should not be
regarded as investigational or for research. This laboratory is
certified under the Clinical Laboratory Improvement Amendments of
1988 (CLIA) as qualified to perform high complexity clinical
laboratory testing.

Primary Pathologist:

Electronically Signed Out by:

Addendum

Results from

HER2 by FISH: 1.4/Not Amplified

Electronically Signed Out by

Clinical History

Left breast cancer.

Intraoperative Consultation

A - Left sentinel node: Metastatic cancer. (Microscopic frozen
section).

[page 3 of 3]
B - Left sentinel node #2: Negative. (Microscopic frozen section).

Gross Description

A - The specimen is received fresh for frozen section labeled "left sentinel node." The specimen consists of a pink-tan lymph node measuring 2.5 x 1.5 x 0.9 cm. The specimen is bisected and entirely frozen in cassette "FS-A1."

B - The specimen is received fresh for frozen section labeled "left sentinel node." The specimen consists of a pink-tan lymph node measuring 3 x 2 x 1.2 cm. The specimen is bisected and entirely frozen in cassette "FS-B1."

C - The specimen is received in formalin and labeled "left breast suture at 6 o'clock." The specimen consists of a mastectomy specimen without axillary tissue measuring 28 x 23.5 x 50 cm and weighing 1559 gm. There is an overlying tan ellipse of skin measuring 22 x 7 cm and showing an eccentric wrinkled brown areola measuring 4.5 x 4.5 cm. Within the center of the areola there is an inverted soft brown nipple measuring 1.1 x 1.1 x 0.9 cm. There are grossly no healed incisions or biopsy sites on the skin surface however the medial edge of the areola is partially stained with blue dye. Attached suture marks the 6 o'clock margin. The deep margin is inked black and the specimen is serially sectioned to reveal an irregular firm tumor between the upper-inner and lower-inner quadrants approximately 1 cm from the nipple measuring 2.5 x 2 x 1.5 cm. The tumor comes to within 3 cm of the deep margin and within 2 cm of the superficial margin (inked blue). Further sectioning reveals a well-circumscribed nodule within the lower-outer quadrant 3.5 cm from the nipple measuring 1.5 x 1 x 1 cm. This nodule comes to within 3 cm of the deep margin. The remaining specimen consists of lobulated fat interspersed with a large amount of tan-white irregularly-indurated tissue with scattered cysts filled with clear fluid measuring up to 0.4 cm in diameter. A lymph node is identified at the axillary margin measuring 1 x 1 x 0.7 cm. Representative sections are submitted in 12 cassettes. Block summary: "1" - vertical section of nipple, "2" - cross-section of nipple, "3-4" - tumor, "5" - superficial and deep margin nearest to tumor, "6" - nodule within the lower-outer quadrant, "7" - upper-inner quadrant, "8" - lower-inner quadrant, "9" - lower-outer quadrant, "10" - upper-outer quadrant, "11" - tissue underlying the nipple stained with blue dye, "12" - bisected lymph node at the axillary margin.

D - The specimen is received in formalin and labeled "left axillary contents." The specimen consists of a tan-yellow portion of axillary fatty tissue measuring 8 x 5.5 x 3.5 cm and weighing 53 gm. Sectioning reveals 11 potential lymph nodes ranging from 0.4 to 2.3 cm in greatest dimensions. The lymph nodes are totally submitted in 4 cassettes. Block summary: "1" - 7 lymph nodes 1 of which is bisected, "2" - 2 bisected lymph nodes, "3" - 1 bisected lymph node, "4" - 1 bisected lymph node.

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic

Source: NCI Genomic Data Commons file 8bb61127-ebb2-4aa1-ba01-7390f25d839e (TCGA-AC-A2BM.9F00B6F4-EE91-4A18-B533-127E39EF8554.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).